Gene-level copy-number profile of tumor specimen TCGA-29-1761-01A from TCGA case TCGA-29-1761, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 80.3 years (29,337 days).
Specimen TCGA-29-1761-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.99d32dd3-0594-46be-96ba-6a981950aa0f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1761-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eaaf09e7-1be5-4ac5-ab45-f8e61b6ac135

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 5,573; copy number 2: 23,327; copy number 3: 23,169; copy number 4: 4,245; copy number 5: 1,826; copy number 6: 137; copy number 7: 676; copy number 8: 284; copy number 9: 84; copy number 10: 49; copy number 11: 56; copy number 12: 106; copy number 13: 17; copy number 14: 159; copy number 15: 41; copy number 22: 63.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1761-01A-01D-0559-01): tumor purity 0.81, ploidy 2.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,282 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:117,672,154–117,997,592, 1 gene, copy number 10 (within-gene range 6–10): AC092691.1.
- chr3:117,719,859–120,450,993, 48 genes, copy number 10: AC092691.3, AC068633.1, AC068633.2, IGSF11, IGSF11-AS1, TEX55, AC083800.1, UPK1B, B4GALT4, B4GALT4-AS1, ARHGAP31, RPS26P21, ARHGAP31-AS1, RNU6-1127P, TMEM39A, POGLUT1, AC073352.1, TIMMDC1, CD80, AC073352.2, ADPRH, PLA1A, RPL10P7, POPDC2, COX17, AC023494.1, CFAP91, AC069444.2, AC069444.1, NR1I2, PHBP8, GSK3B, AC092910.4, AC078856.1, AC092910.1, AC092910.2, AC092910.3, RN7SL762P, RN7SL397P, GPR156, Y_RNA, AC063952.2, LRRC58, AC063952.1, AC063952.4, AC063952.3, FSTL1, MIR198.
- chr3:166,569,693–171,996,871, 96 genes, copy number 8–11 (broad region; genes not listed).
- chr8:123,123,106–129,683,770, 117 genes, copy number 7–12 (within-gene range 3–12) (broad region; genes not listed).
- chr12:66,767–24,562,544, 633 genes, copy number 7 (within-gene range 2–9) (broad region; genes not listed).
- chr12:24,212,421–39,170,880, 235 genes, copy number 7–15 (broad region; genes not listed).
- chr15:31,923,438–32,173,018, 1 gene, copy number 9 (within-gene range 3–9): CHRNA7.
- chr15:32,175,247–32,186,475, 2 genes, copy number 9: Y_RNA, AC068448.1.
- chr17:47,522,942–48,061,545, 29 genes, copy number 8 (within-gene range 3–8): NPEPPS, Y_RNA, AC025682.1, KPNB1, AC015674.1, TBKBP1, TBX21, OSBPL7, MRPL10, LRRC46, SCRN2, SP6, AC018521.3, AC018521.7, AC018521.5, SP2, SP2-AS1, AC018521.6, PNPO, AC018521.1, AC018521.2, PRR15L, CDK5RAP3, AC018521.4, COPZ2, MIR152, NFE2L1-DT, NFE2L1, AC004477.1.
- chr18:44,039,471–46,266,992, 33 genes, copy number 11: AC083760.1, RNA5SP455, AC110014.1, LINC01478, KRT8P5, MLECP1, SETBP1-DT, SETBP1, AC021766.1, MIR4319, AC105074.1, AC090376.1, SLC14A2, SLC14A2-AS1, AC021517.1, AC021517.3, AC091151.2, AC091151.7, AC091151.1, AC023421.1, AC023421.2, SLC14A1, AC087685.1, SIGLEC15, EPG5, PSTPIP2, RN7SKP26, AC012569.1, RNY4P37, ATP5F1A, HAUS1, RNU6-1278P, C18orf25.
- chr19:27,638,483–30,713,538, 65 genes, copy number 13–22 (within-gene range 3–22) (broad region; genes not listed).
- chr20:46,455,033–47,356,889, 22 genes, copy number 8 (within-gene range 4–8): AL031686.1, MKRN7P, ZNF840P, ZNF334, OCSTAMP, SLC13A3, AL133520.1, TP53RK, AL031055.1, SLC2A10, RN7SKP33, AL354766.1, EYA2, AL354766.2, GAPDHP54, AL121776.1, AL022342.1, MIR3616, ZMYND8, AL031666.2, AL031666.3, AL031666.1.

Autosomal genes at a single copy (total copy number 1): 3,771. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
